Gene-level copy-number profile of specimen HCM-BROD-0055-C64-85A from HCMI case HCM-BROD-0055-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.4 years (162 days).
Specimen HCM-BROD-0055-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41ec43b1-96ba-4a1a-acbc-1a5a0fda8adf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0055-C64-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/f1d0a971-ea2d-40c9-b91f-a069457041a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 2,910; copy number 2: 54,091; copy number 3: 1,798; copy number 4: 43; copy number 5: 2; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,047,695–242,175,634, 6 genes (within-gene range 0–2): LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr4:53,286–107,114, 2 genes (within-gene range 0–1): ZNF595, AC253576.1.
- chr7:137,318,592–137,326,953, 1 gene (within-gene range 0–2): AC078842.2.
- chr8:144,973,589–145,048,889, 6 genes: ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1.
- chr11:65,386,621–65,538,704, 16 genes (within-gene range 0–2): FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.
- chr11:134,985,683–135,075,908, 2 genes: AP003062.1, LINC02684.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:83,220,527–83,240,804, 2 genes: AC139099.1, RPL23AP87.
- chr19:58,467,045–58,605,223, 19 genes: ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:46,525,618–46,691,226, 5 genes (within-gene range 0–2): RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.
- chr22:50,735,825–50,801,309, 6 genes: AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,325,372–113,425,548, 1 gene, copy number 5 (within-gene range 4–5): AC016745.1.
- chr14:106,874,583–106,879,812, 2 genes, copy number 6: IGHV7-81, IGHVIII-82.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
